Somatic mutation profile of tumor specimen TCGA-Q1-A5R1-01A (aliquot TCGA-Q1-A5R1-01A-11D-A28B-09) from TCGA case TCGA-Q1-A5R1, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 32.0 years (11,705 days).
Specimen TCGA-Q1-A5R1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 587cfb29-a25a-4e3f-96ee-f551db11fd34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q1-A5R1-10A (Blood Derived Normal), aliquot TCGA-Q1-A5R1-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8f4f095-06d8-412c-9886-a27aec5a8a0d

The open-access MAF lists 60 somatic variants for this specimen: 46 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 36, Silent 14, Nonsense Mutation 7, Frame Shift Ins 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 5/99 reads (5%) | catalogued as rs794727636, CM034954, COSV50274000; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 62/111 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC008397.2 | c.711C>T p.F237= | Splice Region (SNP) | VAF 23/61 reads (38%) | catalogued as COSV53207056; called by muse, mutect2, varscan2
- ADGRG7 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV56301131; called by muse, mutect2, varscan2
- ARF4 | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); catalogued as COSV57714666, COSV57715913; called by muse, mutect2, varscan2
- BATF2 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as rs564496581, COSV100101788, COSV57251260; called by muse, mutect2, varscan2
- BEND7 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 39/118 reads (33%) | PolyPhen benign (0.199); catalogued as rs780674764, COSV61988029; called by muse, mutect2, varscan2
- C7orf57 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV62364139; called by muse, mutect2, varscan2
- CCAR1 | c.2809T>C p.C937R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56274277; called by muse, mutect2, varscan2
- CREB3 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59211631; called by muse, mutect2, varscan2
- CTCF | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV50516003, COSV99064249; called by muse, mutect2, varscan2
- DCAF1 | c.2444G>A p.R815Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); catalogued as COSV100244354, COSV60046479; called by muse, mutect2, varscan2
- DNAJC14 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1481142295, COSV57912186, COSV57914103; called by muse, mutect2, varscan2
- ELAVL2 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 11/108 reads (10%) | catalogued as COSV56370455; called by muse, mutect2, varscan2
- FAM155B | c.1236C>A p.S412R | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.124); catalogued as COSV52937785; called by muse, mutect2, varscan2
- FANCA | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV66883760; called by muse, mutect2, varscan2
- FGF11 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs201458275, COSV53441168; called by muse, mutect2, varscan2
- FMN2 | c.4126C>A p.H1376N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1215322379, COSV60452596, COSV60456452; called by muse, mutect2, varscan2
- GAB2 | c.1012G>A p.A338T (on ENST00000361507 / NM_080491.3; = p.A300T on NM_012296.3) | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs1290335112, COSV100416737; called by muse, mutect2
- GNAT1 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs375795574; called by muse, mutect2, varscan2
- HASPIN | c.2122G>C p.E708Q | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV53999599; called by muse, mutect2, varscan2
- IFI16 | c.1759G>T p.E587* (on ENST00000295809 / NM_001364867.2; = p.E531* on NM_005531.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 4/56 reads (7%) | catalogued as COSV99858045; called by muse, mutect2
- INCENP | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53920929; called by muse, mutect2, varscan2
- IRAK3 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV54165719; called by muse, mutect2, varscan2
- KCNJ8 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV53718202; called by muse, mutect2, varscan2
- KDM3B | c.2036C>G p.S679C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.174); catalogued as COSV100070129; called by muse, mutect2, varscan2
- KDM3B | c.2153C>G p.S718C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as rs754696681, COSV58695018; called by muse, mutect2, varscan2
- KDM3B | c.2456C>G p.S819* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV58695049; called by muse, mutect2, varscan2
- KTN1 | c.1894A>T p.S632C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68025527; called by muse, mutect2, varscan2
- LPCAT2 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as rs774624045, COSV50896669; called by muse, mutect2, varscan2
- LSM3 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100025579; called by muse, mutect2
- LY6G6F-LY6G6D | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as rs780044897, COSV101012227; called by muse, mutect2
- MAGEA1 | c.176A>G p.Q59R | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV100756673; called by muse, mutect2
- MIA2 | c.1664C>T p.S555L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV54481869, COSV54486247; called by muse, mutect2, varscan2
- NELFCD | c.1079A>G p.D360G (on ENST00000602795; = p.D342G on NM_198976.4) | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV99413711; called by muse, mutect2
- PHKA2 | c.1411A>G p.I471V | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as rs779157238, COSV66056140, COSV66056999; called by muse, mutect2, varscan2
- SLC10A3 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV54837428; called by muse, mutect2, varscan2
- SLC37A3 | c.796A>C p.N266H | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV58266602; called by muse, mutect2, varscan2
- SLC44A1 | c.1927G>C p.D643H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV58267361; called by muse, mutect2, varscan2
- SLX4 | c.5165G>C p.C1722S | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as COSV53568428; called by muse, mutect2, varscan2
- SRRD | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV53226295, COSV53227768; called by muse, mutect2
- VARS1 | c.3529G>A p.A1177T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs756380009, COSV63305112; called by muse, mutect2, varscan2
- YES1 | c.1034A>C p.Y345S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58852901; called by muse, mutect2, varscan2
- ZNF214 | c.232T>G p.Y78D | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV53483601; called by muse, mutect2, varscan2
- TET1 | c.1120dup p.H374Pfs*9 | Frame Shift Ins (INS) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- THOC5 | c.1377_1380del p.T460* | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel, varscan2
- DUS3L | c.723C>T p.P241= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1173714241, COSV57833587; called by muse, mutect2, varscan2
- HDAC1 | c.1071G>A p.E357= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100269641; called by muse, mutect2
- HNRNPUL2 | c.1180C>T p.L394= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV57133768; called by muse, mutect2, varscan2
- HOXC8 | c.579G>A p.V193= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV50002799; called by muse, mutect2, varscan2
- MUC4 | c.13791C>T p.V4597= (on ENST00000463781 / NM_018406.7; = p.V361= on NM_004532.6) | Silent (SNP) | VAF 76/117 reads (65%) | catalogued as COSV57801846; called by muse, mutect2, varscan2
- MYORG | c.63C>T p.Y21= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV52627654; called by muse, mutect2, varscan2
- PLTP | c.21C>T p.L7= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV62466298; called by muse, mutect2, varscan2
- RASD2 | c.426C>T p.N142= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs772031079, COSV53352203; called by muse, mutect2, varscan2
- SYNJ1 | c.4269A>G p.Q1423= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as rs1379288428, COSV100449568; called by muse, mutect2
- TMEM52B | c.279C>T p.H93= (on ENST00000381923 / NM_001079815.1; = p.H73= on NM_153022.4) | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs145013082; called by muse, mutect2, varscan2
- TRIB2 | c.627C>T p.L209= | Silent (SNP) | VAF 32/140 reads (23%) | catalogued as rs1371900568, COSV50223963, COSV50230692; called by muse, mutect2, varscan2
- TSC1 | c.216C>G p.L72= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV53772922; called by muse, mutect2, varscan2
- TSKS | c.1572C>T p.D524= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs1222918710, COSV55879087; called by muse, mutect2, varscan2
- ZNF490 | c.27C>T p.F9= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV58482729; called by muse, mutect2, varscan2
